Gene-level copy-number profile of tumor specimen AP-E7CU-SG from APOLLO case AP-E7CU, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3.
Specimen AP-E7CU-SG: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e20cc2ac-555d-4bcb-9c41-f38e4696675b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-E7CU-BT (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/3dbaba06-44cc-42f6-b254-4542375fe650

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 22; copy number 2: 245; copy number 3: 10,464; copy number 4: 16,519; copy number 5: 5,440; copy number 6: 11,931; copy number 7: 6,218; copy number 8: 6,226; copy number 9: 761; copy number 10: 743; copy number 11: 170; copy number 12: 50; copy number 13: 52; copy number 14: 28; copy number 15: 2.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr11:86,649–186,136, 6 genes (within-gene range 0–4): OR4F2P, AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P.
- chr12:6,344,554–6,391,571, 3 genes: RN7SL391P, SCNN1A, LTBR.
- chr19:43,007,656–43,186,536, 6 genes (within-gene range 0–4): PSG11, CEACAMP8, PSG2, CEACAMP9, AC005392.1, PSG5.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,806 genes in 44 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–2,547,460, 165 genes, copy number 9–12 (broad region; genes not listed).
- chr1:207,034,366–207,081,024, 2 genes, copy number 12 (within-gene range 8–12): PFKFB2, YOD1.
- chr1:234,372,186–234,980,804, 22 genes, copy number 9: AL355472.3, COA6-AS1, COA6, TARBP1, LINC01354, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3.
- chr2:162,267,074–162,371,595, 2 genes, copy number 9 (within-gene range 6–9): IFIH1, GCA.
- chr3:142,964,497–143,060,725, 1 gene, copy number 9 (within-gene range 6–9): U2SURP.
- chr6:32,578,769–32,668,383, 4 genes, copy number 10: HLA-DRB1, HLA-DQA1, HLA-DQB1, HLA-DQB1-AS1.
- chr6:32,812,763–33,457,544, 59 genes, copy number 9: HLA-DOB, AL669918.1, TAP2, PSMB8, PSMB8-AS1, PSMB9, TAP1, PPP1R2P1, HLA-Z, HLA-DMB, AL645941.2, HLA-DMA, BRD2, AL645941.1, AL645941.3, HLA-DOA, HLA-DPA1, HLA-DPB1, RPL32P1, HLA-DPA2, COL11A2P1, HLA-DPB2, HLA-DPA3, HCG24, COL11A2, RXRB, RNY4P10, SLC39A7, HSD17B8, MIR219A1, RING1, ZNF70P1, HTATSF1P1, AL645940.1, HCG25, VPS52, RPS18, B3GALT4, WDR46, MIR6873, PFDN6, MIR6834, RGL2, TAPBP, ZBTB22, DAXX, SMIM40, SMIM40, MYL8P, LYPLA2P1, RPL35AP4, KIFC1, RPL12P1, PHF1, CUTA, SYNGAP1, SYNGAP1-AS1, MIR5004, ZBTB9.
- chr6:45,880,827–48,214,794, 36 genes, copy number 9: CLIC5, RNU6-754P, AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2, AL359633.1, AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1, TNFRSF21, B3GNTL1P2, AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P, PTCHD4, HNRNPA3P4, RBMXP1.
- chr7:37,032–1,237,326, 36 genes, copy number 9: AC215522.1, AC093627.1, AC093627.6, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC226118.1, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1, DNAAF5, SUN1, GET4, AC073957.3, ADAP1, COX19, CYP2W1, C7orf50, MIR339, AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1, ZFAND2A, ZFAND2A-DT, UNCX.
- chr7:1,428,465–1,560,821, 7 genes, copy number 10: MICALL2, AC102953.1, AC102953.2, INTS1, AC093734.1, MAFK, TMEM184A.
- chr7:2,234,195–4,269,000, 29 genes, copy number 10: MRM2, NUDT1, SNX8, MIR6836, IMMP1LP3, EIF3B, AC004840.1, AC004840.2, CHST12, GRIFIN, LFNG, MIR4648, BRAT1, IQCE, TTYH3, AMZ1, GNA12, AC006028.1, CARD11, CARD11-AS1, RN7SKP130, AC024028.1, AC073316.1, AC073316.2, SDK1-AS1, SDK1, AC092427.1, AC011284.1, AC017000.1.
- chr7:6,952,625–7,104,482, 1 gene, copy number 10 (within-gene range 8–10): AC079804.3.
- chr7:7,078,302–11,520,175, 52 genes, copy number 9–10 (within-gene range 7–10): AC092104.1, Y_RNA, C1GALT1, AC005532.2, AC005532.1, AC079448.1, COL28A1, AC004982.1, AC004982.2, MIOS, AC004948.1, RPA3, UMAD1, AC007161.3, AC007161.2, AC007161.1, RNU6-534P, CCNB2P1, AC006042.3, GLCCI1-DT, GLCCI1, AC006042.2, ICA1, AC006042.1, AC007009.1, AC007128.1, AC007128.2, NXPH1, AC009500.1, AC004852.2, AC004852.1, AC004852.3, GAPDHP68, AC060834.2, PER3P1, AC060834.1, AC006363.1, AC010991.1, AC004936.1, AC004879.1, U3, MGC4859, HSPA8P8, AC009945.1, AC004415.1, Y_RNA, NDUFA4, AC007029.1, PHF14, RPL23AP52, AC004160.1, NPM1P11.
- chr7:12,211,270–19,002,416, 73 genes, copy number 9–10 (broad region; genes not listed).
- chr7:30,027,404–30,923,812, 32 genes, copy number 9 (within-gene range 8–9): PLEKHA8, AC007285.1, AC007036.4, AC007036.5, MTURN, AC007036.2, AC007036.3, RPS27P16, AC007036.1, ZNRF2, MIR550A1, MIR550B1, AC006978.2, AC006978.1, LINC01176, NOD1, AC006027.1, GGCT, AC005154.5, GARS1-DT, AC005154.2, AC005154.4, AC005154.1, AC005154.3, GARS1, CRHR2, INMT, AC006022.1, INMT-MINDY4, MINDY4, AC004691.1, AC004691.2.
- chr7:38,257,879–38,340,998, 14 genes, copy number 14: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,354,517, 3 genes, copy number 14 (within-gene range 8–14): TRGV5P, TRGV5, TRGV4.
- chr7:56,011,051–56,063,989, 4 genes, copy number 9: PSPH, CCT6A, SNORA22B, SNORA15.
- chr8:100,257,060–100,501,148, 7 genes, copy number 9 (within-gene range 7–9): RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2.
- chr8:125,091,679–126,292,788, 13 genes, copy number 9 (within-gene range 8–9): NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1.
- chr8:126,766,196–145,066,685, 331 genes, copy number 9–15 (broad region; genes not listed).
- chr9:12,134–89,850, 7 genes, copy number 10: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1.
- chr9:12,685,439–12,823,060, 4 genes, copy number 9: TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L.
- chr9:33,019,682–33,473,930, 17 genes, copy number 9: LAGE3P1, DNAJA1, SMU1, B4GALT1, B4GALT1-AS1, RNU4ATAC15P, SPINK4, BAG1, CHMP5, NFX1, Y_RNA, AQP7, AL356218.2, AQP3, AL356218.1, NOL6, MIR6851.
- chr9:60,914,407–61,789,426, 18 genes, copy number 9: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2, RN7SL722P.
- chr9:61,861,625–61,945,136, 7 genes, copy number 9: AL391987.2, AL391987.1, AL391987.4, AL391987.3, Y_RNA, FAM242E, CR769775.1.
- chr10:5,412,557–5,459,056, 1 gene, copy number 12: NET1.
- chr13:87,672,615–114,337,626, 360 genes, copy number 9–13 (broad region; genes not listed).
- chr14:22,197,446–22,482,959, 1 gene, copy number 9 (within-gene range 7–9): AC244502.1.
- chr14:22,281,105–22,524,381, 58 genes, copy number 9: TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34, TRAJ33, TRAJ32, TRAJ31, TRAJ30, TRAJ29, TRAJ28, TRAJ27, TRAJ26, TRAJ25, TRAJ24, TRAJ23, TRAJ22, TRAJ21, TRAJ20.
- chr14:22,547,506–22,552,156, 1 gene, copy number 9: TRAC.
- chr16:11,555–85,851, 11 genes, copy number 9 (within-gene range 6–9): DDX11L10, WASH4P, MIR6859-4, Z84723.1, WASIR2, IL9RP3, POLR3K, SNRNP25, RHBDF1, Z69720.2, MPG.
- chr18:20,946,906–26,391,685, 105 genes, copy number 10–12 (within-gene range 7–12) (broad region; genes not listed).
- chr18:26,348,347–33,441,101, 93 genes, copy number 10 (broad region; genes not listed).
- chr20:87,250–543,835, 17 genes, copy number 9: DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA, CSNK2A1.
- chr20:5,318,268–5,503,189, 1 gene, copy number 9 (within-gene range 8–9): AL121757.2.
- chr20:5,426,892–8,968,360, 49 genes, copy number 9: LINC00658, AL121757.1, LINC00654, LINC01729, RPS18P1, AL109935.1, GPCPD1, EIF4EP1, SHLD1, RNU1-55P, CHGB, KANK1P1, TRMT6, MCM8, AL035461.3, Y_RNA, AL035461.1, MCM8-AS1, AL035461.2, RN7SL498P, CRLS1, LRRN4, AL118505.1, FERMT1, TARDBPP1, AL109618.1, AL109618.2, AL109618.3, CASC20, LINC01713, BMP2, AL096799.1, LINC01428, AL080248.1, LINC01751, LINC01706, MIR8062, RN7SL547P, AL031679.1, AL021879.1, HAO1, TMX4, AL021396.1, PLCB1, PHKBP1, PLCB1-IT1, RNU105B, AL445567.1, AL445567.2.
- chr20:30,214,765–32,032,180, 55 genes, copy number 11–13 (within-gene range 7–13): CFTRP3, LINC01597, AL121762.1, AL121762.2, Y_RNA, FAM242A, FRG1BP, MLLT10P1, 5_8S_rRNA, ANKRD20A21P, U6, RNA5SP528, DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L.
- chr20:43,189,998–45,670,270, 94 genes, copy number 9–10 (broad region; genes not listed).
- chr21:9,369,285–9,914,846, 10 genes, copy number 14: CR381653.2, NCOR1P4, AC124864.1, AC124864.2, U1, LINC01667, AC018692.2, RN7SL52P, SNORA70, AC018692.1.

Autosomal genes at a single copy (total copy number 1): 22. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
